TCGA case TCGA-3U-A98E — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Chicago. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e0df1fef-c650-4088-a974-26f712ed4f64

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Alive.

Diagnoses (5)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 71.9 years (26,264 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,916 days (5.2 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Amatuximab; Days to treatment start: 61 days; Days to treatment end: 509 days (1.4 years); Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 61 days; Days to treatment end: 173 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Apitolisib; Days to treatment start: 802 days (2.2 years); Days to treatment end: 1,060 days (2.9 years); Treatment outcome: Partial Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Tivantinib; Days to treatment start: 1,286 days (3.5 years); Days to treatment end: 1,430 days (3.9 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Anti-DR5 Agonistic Antibody DS-8273a; Days to treatment start: 1,446 days (4.0 years); Days to treatment end: 1,489 days (4.1 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 1,524 days (4.2 years); Days to treatment end: 1,551 days (4.2 years); Treatment dose: 50 Gy; Treatment outcome: Partial Response; Number of fractions: 20; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 1,543 days (4.2 years); Days to treatment end: 1,551 days (4.2 years); Treatment dose: 15 Gy; Treatment outcome: Partial Response; Number of fractions: 7; Treatment anatomic sites: Regional Site.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Lower limb, NOS; Laterality: Right; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thorax, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.2 years (26,381 days); Days to diagnosis: 117 days; Prior treatment: Yes.
4. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant). Age at diagnosis: 75.3 years (27,521 days); Days to diagnosis: 1,257 days (3.4 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
5. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant). Age at diagnosis: 75.8 years (27,689 days); Days to diagnosis: 1,425 days (3.9 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (8 entries)
- Day 117 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Thorax, NOS.
- Day 1,257 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to progression: 1,257 days (3.4 years).
- Day 1,425 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to progression: 1,425 days (3.9 years).
- Days to follow up: 1,426 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,684 days (4.6 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 90; Timepoint: Post Adjuvant Therapy.
- Follow-up contact recording only the day: day 1,916.

Molecular and laboratory tests
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.4].

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3U-A98E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 390 mg.
  Slide TCGA-3U-A98E-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3U-A98E-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3U-A98E-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Amatuximab (MORab-009).
- Drug treatment 3: Pharmaceutical therapy drug name: Pemetrexed (Alimta).
- Drug treatment 4: Pharmaceutical therapy drug name: GDC-0980.
- Drug treatment 5: Pharmaceutical therapy drug name: Tivantinib (ARQ-197).
- Drug treatment 6: Pharmaceutical therapy drug name: DS-8273a.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Leg; Other malignancy histological type: Basal Cell Carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Excision.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,916 days; disease-specific survival: no event (censored), 1,916 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,257 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3U-A98E-01A-11D-A39Q-01): tumor purity 0.81, ploidy 2.04, whole-genome doublings 0.
